Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4346, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4346-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

Right renal mass.

Specimens Submitted:

- 1: Kidney, right, total nephrectomy [REDACTED]
- 2: Lymph node, precaval and paracaval, excision [REDACTED]
- 3: Adrenal gland and suprahilar lymph nodes, right, resection [REDACTED]

DIAGNOSIS:

1. Kidney, right, total nephrectomy [REDACTED]

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 6.9 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Invasion into renal sinus muscular branches of renal vein is identified.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild arteriosclerotic changes, and a benign cortical cyst

Adrenal Gland:

Not identified

(See part 3)

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

-
2. Lymph node, precaval and paracaval, excision [REDACTED]

Lymph Nodes:

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Not involved
Number of nodes examined:21

3. Adrenal gland and supra hilar lymph nodes, right, resection
Benign adrenal gland
Multiple benign adrenal cortical nodules in the surrounding soft tissue
No lymph nodes identified

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	
	RECUT	
	RECUT	

Gross Description:

1). The specimen is received fresh labeled "Right kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 608 g in total. The total dimensions of the specimen are 22 x 12 x 6.5 cm. The kidney itself measures 15 x 7.5 x 5 cm. The outer surface of the perinephric fat is inked black. The attached ureter measures 9.0 cm in length and 0.4 cm in diameter. The attached renal vein measures 1.5 cm in length and 0.8 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. Adrenal gland is not identified. The kidney is bivalved to reveal a well-circumscribed, lobulated, yellow-tan hemorrhagic cortico-medullary tumor measuring 6.9 x 4.9 x 4.0 cm. The tumor is situated in the upper pole of the kidney, and grossly impinges the sinus fat and renal pelvis, but does not show any definite invasion. The adjacent vessels appear grossly free of tumor. The tumor bulges into the perinephric fat, which shows possible tumor involvement. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. There is a cystic area identified measuring 1.1 x 1.0 cm, which is lined by unremarkable brown renal parenchyma and filled with clear fluid. The cortex measures 3.0 cm and the calyces appear normal. On complete opening of the ureter, renal pelvis, and collecting ducts, they show smooth white tan unremarkable mucosa. No lymph nodes are identified in the perinephric fat. The specimen has been photographed.

Summary of sections:

UM -- ureteral margin
VM-vessel margins
FUP-representative section of fat from upper pole
T-- tumor
HF-- hilar fat
TP-tumor and renal pelvis
TSF -- tumor with sinus fat
TSFV-tumor with sinus fat and adjacent vessel
TN-- tumor with adjacent kidney
RS-- representative section kidney, cystic area
TPNF -- tumor and perinephric fat

2). The specimen is received fresh, labeled "Precaval and paracaval lymph nodes" and consists of multiple pink tan fatty lymph nodes measuring from 0.5 to 1.7 cm in greatest dimension. The lymph nodes are entirely submitted.

Summary of sections:

LN- lymph nodes

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

3). The specimen is received fresh, labeled "Right adrenal gland, and supra hilar lymph nodes" and consists of an adrenal gland with attached yellow tan adipose tissue measuring 8 x 4.5 x 1 cm and weighing 20 g in total. Serial sections reveal a golden yellow adrenal gland parenchyma measuring 4 x 1.8 x 1.5 cm. On cross sections, the gland is grossly unremarkable. A few possible lymph nodes are identified ranging from 0.6 to 1.4 cm in greatest dimension. The gland is entirely submitted. All identified lymph nodes are submitted.

Summary of sections:

LN -lymph nodes

SS- serial sections adrenal gland

Summary of Sections:

Part 1: Kidney, right, total nephrectomy

Block	Sect. Site	PCs
1	FUP	1
1	HF	1
1	RS	1
2	T	2
1	TF	1
1	TN	1
1	TP	1
4	TPNF	4
1	TSFV	1
2	UM	2
1	VM	1

Part 2: Lymph node, precaval and paracaval, excision

Block	Sect. Site	PCs
4	LN	4

Part 3: Adrenal gland and supra hilar lymph nodes, right, resection

Block	Sect. Site	PCs
1	LN	3
8	SS	8

Source: NCI Genomic Data Commons file f1e4a614-723b-44bf-a63b-16395eac18b3 (TCGA-BP-4346.A8962FBA-E477-42C3-9FD8-DEB184C012FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).